Gene-level copy-number profile of tumor specimen TCGA-CD-A489-01A from TCGA case TCGA-CD-A489, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.9 years (21,517 days).
Specimen TCGA-CD-A489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0454f859-7f42-4ff3-9069-cab9e0a897a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A489-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f16b4901-a10d-4fac-a2d5-f95cea8b5813

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 26,757; copy number 2: 31,755; copy number 3: 1,112; copy number 4: 48; copy number 5: 120; copy number 10: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-A489-01A-11D-A24C-01): tumor purity 0.47, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–182,145,249, 10 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr4:182,144,852–182,190,382, 2 genes: AC108142.1, MIR1305.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,686,431–40,665,181, 131 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
